Somatic mutation profile of tumor specimen ALCH-B01K-TTP1-A (aliquot ALCH-B01K-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B01K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,820 days).
Specimen ALCH-B01K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 234885e1-9f96-40a6-8743-e2517bc7fc0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01K-NB1-A (Blood Derived Normal), aliquot ALCH-B01K-NB1-A-2-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d5039d6-9719-4d45-bac2-2a5ec65eaa46

The open-access MAF lists 265 somatic variants for this specimen: 180 protein-altering or splice-affecting, 68 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 68, Nonsense Mutation 17, Intron 8, Splice Site 4, RNA 3, 3'UTR 3, Splice Region 3, 5'Flank 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1455382755; called by muse, mutect2
- ALS2 | c.2606A>T p.Q869L | Missense Mutation (SNP) | VAF 22/571 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as CM1310481; called by muse, mutect2
- AMER3 | c.477C>G p.C159W | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58467725; called by muse, mutect2
- APOB | c.9775G>T p.E3259* | Nonsense Mutation (SNP) | VAF 22/401 reads (5%) | catalogued as COSV51945459; called by muse, mutect2
- B3GALT1 | c.672G>T p.R224S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.569); catalogued as COSV59909358; called by muse, mutect2
- CCSER1 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs1358668974, COSV61432904; called by muse, mutect2
- CDH13 | c.342del p.D116Tfs*31 | Frame Shift Del (DEL) | VAF 13/133 reads (10%) | catalogued as rs1567763530, COSV51808407; called by mutect2, pindel
- CEP128 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 20/478 reads (4%) | catalogued as COSV55390632; called by muse, mutect2
- COL14A1 | c.2847G>T p.R949S | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52858802; called by muse, mutect2, varscan2
- CTNNA3 | c.2160-1G>T p.X720_splice | Splice Site (SNP) | VAF 21/228 reads (9%) | catalogued as COSV65524946; called by muse, mutect2
- CYBB | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 35/640 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781887034, COSV66084815; called by muse, mutect2
- DDR2 | c.1783C>A p.L595I | Missense Mutation (SNP) | VAF 24/567 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV63371873; called by muse, mutect2
- DHRS7B | c.934A>T p.M312L | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1452295600, COSV60888111; called by muse, mutect2
- FAM131B | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 34/661 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1205683629; called by muse, mutect2
- FCN1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65662364; called by muse, mutect2
- FOXI1 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 35/633 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60389679; called by muse, mutect2
- GFM1 | c.1801G>T p.G601C | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51832865; called by muse, mutect2
- GREB1L | c.4344C>A p.Y1448* | Nonsense Mutation (SNP) | VAF 8/131 reads (6%) | catalogued as COSV99336676; called by muse, mutect2
- HOXD10 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50892833; called by muse, mutect2
- IRF4 | c.927C>A p.S309R | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.925); catalogued as rs1302019454; called by muse, mutect2
- ITGAD | c.243C>A p.I81= | Splice Region (SNP) | VAF 14/172 reads (8%) | catalogued as rs976487968; called by muse, mutect2
- LHCGR | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 26/553 reads (5%) | catalogued as COSV54300283; called by muse, mutect2
- MAMLD1 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs782263607; called by muse, mutect2
- NOM1 | c.1848G>T p.W616C | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1021368811; called by muse, mutect2
- NUFIP2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV56603507; called by muse, mutect2
- OR51A7 | c.463T>A p.L155I | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as COSV63788310; called by muse, mutect2
- PCDH11X | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV53463546; called by muse, mutect2
- PCF11 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 11/248 reads (4%) | catalogued as COSV53531254; called by muse, mutect2
- PLPPR4 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64565278; called by muse, mutect2
- PNCK | c.106G>T p.G36C (on ENST00000340888 / NM_001366975.1; = p.G119C on NM_001039582.3) | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV61745485; called by muse, mutect2
- PON3 | c.47T>C p.L16S | Missense Mutation (SNP) | VAF 42/639 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs747055745; called by muse, mutect2
- PPP1R12C | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1175807481, COSV54737263; called by muse, mutect2
- PROX1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV54776823; called by muse, mutect2
- RTL9 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101511773; called by muse, mutect2
- SAG | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101300632; called by muse, mutect2
- SDHA | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99372134; called by muse, mutect2
- SHC4 | c.1784G>T p.R595I | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs1469296256; called by muse, mutect2
- SLC13A2 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782709113, COSV58993750; called by muse, mutect2
- SLC22A6 | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1480422915; called by muse, mutect2
- SLC30A10 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1330862242; called by muse, mutect2
- SOX6 | c.2101G>A p.D701N (on ENST00000528429 / NM_001145819.2; = p.D674N on NM_017508.3) | Missense Mutation (SNP) | VAF 29/668 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV57046567; called by muse, mutect2
- SPTA1 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 19/559 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV100935413; called by muse, mutect2
- TFF2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs756553873, COSV99367219; called by muse, mutect2
- TMEM131 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV51775323; called by muse, mutect2
- TNRC18 | c.5599C>G p.L1867V | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1468912125; called by muse, mutect2
- UTP4 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 27/504 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs763509506, COSV58732494; called by muse, mutect2
- ZNF469 | c.3508G>T p.A1170S (on ENST00000437464; = p.A1198S on NM_001367624.2) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.359); catalogued as rs1365252134; called by muse, mutect2
- ZNF480 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100574134; called by muse, mutect2
- ZNF626 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV104441897; called by muse, mutect2
- ZNF804A | c.1693A>G p.K565E | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs1438260054, COSV56438159; called by muse, mutect2
- ZXDC | c.2213-2A>G p.X738_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as rs1032145952; called by muse, mutect2
- AATF | c.609T>A p.S203R | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- ABCA13 | c.11188G>A p.E3730K | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY2 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGL | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- ALOXE3 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2
- ANGPTL5 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 28/709 reads (4%) | called by muse, mutect2
- ANXA11 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- APOB | c.4040A>G p.Q1347R | Missense Mutation (SNP) | VAF 20/503 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.603); called by muse, mutect2
- ARGFX | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 13/268 reads (5%) | called by muse, mutect2
- ARHGAP31 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ARID1A | c.1087A>T p.S363C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ARRDC5 | c.431T>A p.I144N (on ENST00000381781; = p.I130N on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ATP6V1B1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 22/593 reads (4%) | called by muse, mutect2
- AUTS2 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BRDT | c.2779G>T p.V927L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- C1orf94 | c.749C>T p.T250I (on ENST00000488417 / NM_001134734.2; = p.T60I on NM_032884.5) | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2
- CACNA2D1 | c.2994C>A p.N998K (on ENST00000356253 / NM_001366867.1; = p.N986K on NM_000722.4) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CDCA4 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CDCP1 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- CELSR3 | c.3524T>C p.L1175P | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CHM | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CLDN14 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CLSTN2 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL4A2 | c.3787G>T p.G1263* | Nonsense Mutation (SNP) | VAF 21/330 reads (6%) | called by muse, mutect2
- CPED1 | c.2477T>A p.I826K | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2
- CSMD3 | c.6172C>T p.P2058S (on ENST00000297405 / NM_001363185.1; = p.P1954S on NM_052900.3) | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- DLG1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.583); called by muse, mutect2
- EIF3E | c.324-2A>T p.X108_splice | Splice Site (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- ELF4 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- ELSPBP1 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- ERBB4 | c.2125C>G p.Q709E | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2
- FAM171B | c.1471T>C p.S491P | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- FAM193A | c.3074A>G p.K1025R | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- FBN2 | c.4051C>A p.H1351N | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- FBXL17 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- FGFR2 | c.1624G>T p.G542W | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNA | c.393C>A p.D131E | Missense Mutation (SNP) | VAF 19/414 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- FOXG1 | c.661A>T p.N221Y | Missense Mutation (SNP) | VAF 28/730 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXR2 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.2); called by muse, mutect2
- GRAP2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2
- GTF2I | c.1305-8C>G | Splice Region (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- HADHB | c.955T>A p.L319I | Missense Mutation (SNP) | VAF 26/588 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); called by muse, mutect2
- HBD | c.92+1G>T p.X31_splice | Splice Site (SNP) | VAF 25/561 reads (4%) | called by muse, mutect2
- HEY2 | c.803C>A p.A268D | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.353); called by muse, mutect2
- HIVEP2 | c.3532A>T p.M1178L | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- HJV | c.640G>T p.A214S (on ENST00000336751 / NM_213653.4; = p.A101S on NM_145277.5) | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2
- HNRNPC | c.536A>T p.Q179L (on ENST00000420743; = p.Q166L on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.103); called by muse, mutect2
- HOXD11 | c.927A>T p.Q309H | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL27 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNC1 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2
- KERA | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2
- KIF2B | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 34/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KIF5B | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- KIR3DL2 | c.789A>T p.E263D | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.971); called by muse, mutect2
- KMT2D | c.15521G>C p.R5174P | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRB5 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- MAGEB4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2
- MAGEB5 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MCCC2 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 20/409 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- MRC1 | c.2885T>G p.F962C | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- MUC3A | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2
- MYH4 | c.4013A>T p.Q1338L | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- MYO15A | c.4709G>T p.R1570M | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NAALAD2 | c.1717C>A p.L573M | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.12); called by muse, mutect2
- NBPF22P | n.756C>A | Splice Region (SNP) | VAF 15/256 reads (6%) | called by muse, mutect2
- NEFL | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NFIX | c.1466A>T p.N489I (on ENST00000592199 / NM_001365902.3; = p.T440S on NM_002501.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2
- NIPBL | c.4918C>T p.Q1640* | Nonsense Mutation (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- NLK | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- NLRP9 | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- NOM1 | c.1847G>T p.W616L | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NTNG1 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2
- OBSCN | c.13426G>A p.D4476N | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.343); called by muse, mutect2
- OPA1 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 18/443 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- OR2G2 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR4K13 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5M8 | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.833); called by muse, mutect2
- OSMR | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 20/420 reads (5%) | called by muse, mutect2
- OTOGL | c.382C>G p.Q128E (on ENST00000547103; = p.Q119E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- PALMD | c.1499A>T p.H500L | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2
- PAPOLG | c.1829T>C p.V610A | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); called by muse, mutect2
- PAPSS2 | c.758A>T p.D253V | Missense Mutation (SNP) | VAF 27/537 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDH17 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 32/425 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- PCF11 | c.903G>C p.R301S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- PLOD2 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PMS1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 28/751 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- PODN | c.557C>T p.P186L (on ENST00000395871; = p.P138L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- POLR1A | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.281); called by muse, mutect2
- PPFIA2 | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.07); called by muse, mutect2
- PPP1R12A | c.2954G>C p.R985T | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- PPP4R3C | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- RFPL3 | c.434G>A p.R145K (on ENST00000249007 / NM_001098535.1; = p.R116K on NM_006604.2) | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.22); called by muse, mutect2
- RPRML | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2
- RTL3 | c.978C>A p.N326K | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2
- SCN2A | c.1112G>T p.S371I | Missense Mutation (SNP) | VAF 23/508 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIN3B | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.026); called by muse, mutect2
- SLA | c.544G>A p.A182T (on ENST00000338087 / NM_001045556.3; = p.A222T on NM_006748.4) | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SLAIN1 | c.1313G>T p.G438V (on ENST00000466548; = p.G175V on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC1B | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SOX6 | c.1398C>A p.S466R (on ENST00000528429 / NM_001145819.2; = p.S425R on NM_017508.3) | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- STARD9 | c.11869G>T p.E3957* | Nonsense Mutation (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- SV2A | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); called by muse, mutect2
- SYMPK | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TAF2 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.297); called by muse, mutect2
- TAF3 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 18/449 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- TET1 | c.6160C>G p.L2054V | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TMEM132C | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); called by muse, mutect2
- TMEM59L | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- TNKS1BP1 | c.3332G>T p.R1111L | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.12); called by muse, mutect2
- TPCN1 | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM48 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2
- TRIP10 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TTN | c.75583T>C p.C25195R (on ENST00000591111; = p.C17771R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/398 reads (6%) | PolyPhen probably damaging (0.944); called by muse, mutect2
- TTN | c.62606C>A p.A20869E (on ENST00000591111; = p.A13445E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/580 reads (4%) | PolyPhen benign (0.019); called by muse, mutect2
- TTN | c.61086G>T p.W20362C (on ENST00000591111; = p.W12938C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/289 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UGT2B11 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.15151G>T p.G5051C | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- VPS13B | c.6741G>T p.W2247C | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- WEE1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); called by muse, mutect2
- WIPI2 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- YTHDC2 | c.2657G>T p.R886M | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ZAN | c.2284C>A p.P762T | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ZIM3 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ZNF275 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); called by muse, mutect2
- ZNF518A | c.3429A>G p.I1143M | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ZNF572 | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ZNF615 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- ZNF736 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZNF786 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 14/243 reads (6%) | called by muse, mutect2
- ADGRG4 | c.1872C>T p.S624= | Silent (SNP) | VAF 17/392 reads (4%) | called by muse, mutect2
- AMER1 | c.915G>T p.V305= | Silent (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
- APOB | c.7329C>A p.I2443= | Silent (SNP) | VAF 23/597 reads (4%) | catalogued as COSV99266999; called by muse, mutect2
- BRD1 | c.1296G>A p.K432= | Silent (SNP) | VAF 19/330 reads (6%) | called by muse, mutect2
- C1orf141 | c.1026C>A p.A342= | Silent (SNP) | VAF 28/662 reads (4%) | called by muse, mutect2
- CLHC1 | c.705T>C p.H235= | Silent (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
- COL5A3 | c.4164C>A p.G1388= | Silent (SNP) | VAF 11/209 reads (5%) | called by muse, mutect2
- COL6A2 | c.294C>A p.G98= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- CSF1R | c.867C>A p.T289= | Silent (SNP) | VAF 18/367 reads (5%) | called by muse, mutect2
- CYP1B1 | c.15C>G p.L5= | Silent (SNP) | VAF 28/376 reads (7%) | called by muse, mutect2
- DHX16 | c.798G>A p.E266= | Silent (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- DMTF1 | c.1927C>T p.L643= | Silent (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- DMXL2 | c.4917G>A p.V1639= | Silent (SNP) | VAF 26/413 reads (6%) | called by muse, mutect2
- DTX1 | c.1140G>A p.K380= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- EDNRB | c.825G>T p.V275= (on ENST00000377211 / NM_001201397.1; = p.V185= on NM_000115.5) | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- FPR2 | c.657C>A p.I219= | Silent (SNP) | VAF 17/344 reads (5%) | catalogued as COSV60672730; called by muse, mutect2
- GABRB3 | c.70C>T p.L24= | Silent (SNP) | VAF 14/311 reads (5%) | catalogued as rs1235740453; called by muse, mutect2
- GATA3 | c.552C>G p.L184= | Silent (SNP) | VAF 16/565 reads (3%) | catalogued as rs1219976594, COSV60522096; called by muse, mutect2
- GHRHR | c.666A>G p.A222= | Silent (SNP) | VAF 20/376 reads (5%) | catalogued as COSV100396743; called by muse, mutect2
- GPR32 | c.399C>G p.V133= | Silent (SNP) | VAF 22/529 reads (4%) | catalogued as COSV54515148; called by muse, mutect2
- GPR61 | c.756C>A p.P252= | Silent (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
- HHIPL2 | c.2064C>A p.A688= | Silent (SNP) | VAF 16/423 reads (4%) | called by muse, mutect2
- HOXA3 | c.744G>A p.K248= | Silent (SNP) | VAF 19/340 reads (6%) | catalogued as COSV57826224, COSV57826903; called by muse, mutect2
- HOXD11 | c.747G>A p.P249= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- IGHG4 | c.735G>A p.L245= | Silent (SNP) | VAF 22/648 reads (3%) | catalogued as rs759411359; called by muse, mutect2
- IGKV3D-15 | c.346C>G p.*116= | Silent (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- IGLV3-22 | c.120C>A p.T40= | Silent (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- IQSEC2 | c.3558C>A p.P1186= | Silent (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- ITIH5 | c.2592T>C p.T864= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- KCND2 | c.1059G>A p.K353= | Silent (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- KCNH5 | c.2559G>T p.V853= | Silent (SNP) | VAF 10/231 reads (4%) | catalogued as COSV59760738; called by muse, mutect2
- KCNK18 | c.117G>A p.V39= | Silent (SNP) | VAF 32/672 reads (5%) | catalogued as rs1382077096, COSV100572005; called by muse, mutect2
- LILRA1 | c.6C>A p.T2= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- LRRC23 | c.1002T>A p.R334= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- LRRC32 | c.1800C>T p.C600= | Silent (SNP) | VAF 14/225 reads (6%) | called by muse, mutect2
- METTL7B | c.294C>T p.D98= | Silent (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- MMD2 | c.246G>C p.V82= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- MUC3A | c.831C>A p.S277= | Silent (SNP) | VAF 28/560 reads (5%) | called by muse, mutect2
- MYH8 | c.5742C>T p.D1914= | Silent (SNP) | VAF 34/535 reads (6%) | called by muse, mutect2
- MYL10 | c.486C>A p.A162= | Silent (SNP) | VAF 12/215 reads (6%) | called by muse, mutect2
- NANOG | c.258A>G p.K86= | Silent (SNP) | VAF 17/291 reads (6%) | called by muse, mutect2
- NEUROD1 | c.1071G>A p.*357= | Silent (SNP) | VAF 18/404 reads (4%) | catalogued as rs1226691731; called by muse, mutect2
- NKX3-1 | c.564G>T p.L188= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as rs1481166121; called by muse, mutect2
- NLGN4X | c.1032C>T p.I344= | Silent (SNP) | VAF 18/615 reads (3%) | catalogued as rs1216086207, COSV52012402, COSV52041335; called by muse, mutect2
- NOL8 | c.1083T>C p.S361= | Silent (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- NTF3 | c.330C>A p.T110= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- OR5T2 | c.282C>A p.L94= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV57587700; called by muse, mutect2
- OR8H1 | c.354C>T p.A118= | Silent (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- PABPC5 | c.189T>C p.Y63= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- PAX6 | c.906C>T p.P302= | Silent (SNP) | VAF 40/712 reads (6%) | called by muse, mutect2
- PCDHGA10 | c.981T>C p.D327= | Silent (SNP) | VAF 17/324 reads (5%) | called by muse, mutect2
- POLQ | c.1785C>T p.I595= | Silent (SNP) | VAF 16/371 reads (4%) | called by muse, mutect2
- PREX1 | c.3708C>G p.L1236= | Silent (SNP) | VAF 18/345 reads (5%) | called by muse, mutect2
- RBM20 | c.2017C>A p.R673= | Silent (SNP) | VAF 36/270 reads (13%) | catalogued as CM1410906; called by muse, mutect2, varscan2
- RFX4 | c.1563T>G p.S521= (on ENST00000392842 / NM_213594.3; = p.S427= on NM_032491.6) | Silent (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- RTL9 | c.1836A>G p.G612= | Silent (SNP) | VAF 12/279 reads (4%) | catalogued as rs1391270518; called by muse, mutect2
- RYR3 | c.10395G>A p.Q3465= (on ENST00000389232; = p.Q3466= on NM_001036.6) | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV66790755; called by muse, mutect2
- SCN3A | c.2439C>A p.A813= | Silent (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- SEMA3C | c.2001G>C p.V667= | Silent (SNP) | VAF 17/472 reads (4%) | called by muse, mutect2
- SLC22A25 | c.588C>A p.I196= | Silent (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- SPDYE4 | c.612C>T p.S204= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- TERB1 | c.1965C>A p.L655= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- TGFBR3 | c.2307G>A p.K769= | Silent (SNP) | VAF 22/592 reads (4%) | called by muse, mutect2
- TLR7 | c.597C>A p.A199= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- TNKS1BP1 | c.3333G>T p.R1111= | Silent (SNP) | VAF 17/442 reads (4%) | called by muse, mutect2
- TPCN1 | c.744C>T p.I248= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- ZFHX3 | c.405C>T p.Y135= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV51721687; called by muse, mutect2
- ZSCAN4 | c.843C>G p.S281= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV56591301; called by muse, mutect2, varscan2
- AC008758.3 | n.117G>T | RNA (SNP) | VAF 16/369 reads (4%) | called by muse, mutect2
- AP000769.3 | chr11:65502375 G>A | 5'Flank (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- ENPP2 | c.973-2102C>A | Intron (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- GABRG3 | c.1123-1968G>T | Intron (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- GLB1L3 | c.812-49G>A | Intron (SNP) | VAF 18/384 reads (5%) | catalogued as rs1184590459; called by muse, mutect2
- IFT122 | c.*25C>T | 3'UTR (SNP) | VAF 22/400 reads (6%) | catalogued as rs1560039658; called by muse, mutect2
- ITIH5 | c.940-14465G>T | Intron (SNP) | VAF 15/259 reads (6%) | called by muse, mutect2
- LTN1 | c.-10A>T | 5'UTR (SNP) | VAF 12/402 reads (3%) | called by muse, mutect2
- MECOM | chr3:169149672 G>A | 5'Flank (SNP) | VAF 10/204 reads (5%) | catalogued as rs1214964501; called by muse, mutect2
- NAALADL1 | c.1078+33C>A | Intron (SNP) | VAF 15/281 reads (5%) | called by muse, mutect2
- OR2W5 | n.816T>C | RNA (SNP) | VAF 26/438 reads (6%) | called by muse, mutect2
- PFKM | c.844-16C>T | Intron (SNP) | VAF 17/326 reads (5%) | catalogued as rs1273339747; called by muse, mutect2
- POU3F4 | c.*41C>G | 3'UTR (SNP) | VAF 13/245 reads (5%) | called by muse, mutect2
- RBM14 | c.338-308G>A | Intron (SNP) | VAF 33/311 reads (11%) | called by muse, mutect2, varscan2
- RGS6 | c.*314G>T | 3'UTR (SNP) | VAF 15/278 reads (5%) | called by muse, mutect2
- SHANK2 | c.1174+33065G>A | Intron (SNP) | VAF 32/563 reads (6%) | catalogued as rs1555068283; called by muse, mutect2
- SUMO2P21 | n.197C>A | RNA (SNP) | VAF 30/902 reads (3%) | called by muse, mutect2
